TCGA case TCGA-BR-8058 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4685dc14-1809-47ea-aba9-9bde72f6661b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,658 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,133 days (3.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 8.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the rectum (histology not recorded by GDC). Age at diagnosis: 54.1 years (19,747 days); Days to diagnosis: 89 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 35 days; Disease response: Tumor Free.
- Days to follow up: 532 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 1,133 days (3.1 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3.2; Intermediate dimension: 1.6; Shortest dimension: 0.3.
  Slide TCGA-BR-8058-01A-02-BS2: Section location: Top; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample TCGA-BR-8058-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8058-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Tver.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event site other: Rectum; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Biopsy with Histologic Confirmation.
- Follow-up form 1, New neoplasm event types: New tumor event type: New Primary Tumor.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,133 days; disease-specific survival: no event (censored), 1,133 days; disease-free interval: no event (censored), 1,133 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 89 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8058-01A-31D-2338-01): tumor purity 0.3, ploidy 1.76, whole-genome doublings 0.
